Somatic mutation profile of tumor specimen TCGA-49-4486-01A (aliquot TCGA-49-4486-01A-01D-1265-08) from TCGA case TCGA-49-4486, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.3 years (26,415 days).
Specimen TCGA-49-4486-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aad956cb-4fda-4148-abdc-23f0a65b3db5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4486-11A (Solid Tissue Normal), aliquot TCGA-49-4486-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/740953ea-eeb5-4052-9385-28527d26fc4e

The open-access MAF lists 151 somatic variants for this specimen: 105 protein-altering or splice-affecting, 42 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 42, Nonsense Mutation 7, Splice Site 2, Intron 2, RNA 2, Frame Shift Del 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50262468, COSV50595028; called by muse, mutect2, varscan2
- AC005833.1 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as rs373419543, COSV52899928; called by muse, mutect2, varscan2
- ACER3 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV53601541; called by muse, mutect2, varscan2
- ACVR1 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55121307; called by muse, mutect2, varscan2
- ADAMTS12 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61272347; called by muse, mutect2, varscan2
- ADAMTS12 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs754144817, COSV61272355; called by muse, mutect2, varscan2
- AGER | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV61248360; called by muse, mutect2, varscan2
- ANKRD34A | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV60161687; called by muse, mutect2, varscan2
- AOAH | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV51742917; called by muse, mutect2
- ATP6V1A | c.1827G>C p.Q609H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV56360893, COSV56363660; called by muse, mutect2
- BAZ2A | c.468T>A p.S156R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV51640929; called by muse, mutect2, varscan2
- BOD1L1 | c.3487C>G p.Q1163E | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV50036009, COSV50058336; called by muse, mutect2
- BUB1B | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV55015251; called by muse, mutect2, varscan2
- CD79A | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99701908; called by muse, mutect2, varscan2
- CDH11 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV99217061; called by muse, mutect2, varscan2
- CFAP47 | c.1912T>C p.Y638H | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99934307; called by mutect2, varscan2
- COL7A1 | c.7843G>C p.D2615H | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56475991, COSV56476973; called by muse, mutect2, varscan2
- CRKL | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs1221209545, COSV62883900; called by muse, mutect2, varscan2
- CRYBG1 | c.3143G>A p.R1048K | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV64813628; called by muse, mutect2
- CYP1B1 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53192238; called by mutect2, varscan2
- CYP2C8 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV64878297; called by muse, mutect2, varscan2
- DEPDC4 | c.756C>G p.F252L | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV54554076; called by muse, mutect2
- DLGAP1 | c.1591+1G>T p.X531_splice | Splice Site (SNP) | VAF 17/38 reads (45%) | catalogued as COSV59816354, COSV59823122; called by muse, mutect2, varscan2
- DYNC1I1 | c.648G>C p.L216F | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61467372; called by muse, mutect2, varscan2
- EIF5B | c.1001A>C p.K334T | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV56815619; called by muse, mutect2, varscan2
- EPB41L4B | c.1279G>C p.A427P | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV65798125; called by muse, mutect2, varscan2
- FAM83H | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66354340; called by muse, mutect2, varscan2
- FBXL3 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV62919137; called by muse, mutect2, varscan2
- FBXO5 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV57671349; called by muse, mutect2, varscan2
- FCRL1 | c.1230C>A p.D410E | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as COSV63826542; called by muse, mutect2, varscan2
- G3BP1 | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV62366653; called by muse, mutect2, varscan2
- GABRA2 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as COSV62917610; called by muse, mutect2, varscan2
- GABRB3 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54676421; called by muse, mutect2, varscan2
- GNAQ | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV54120982; called by muse, mutect2
- GNB4 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51710853; called by muse, mutect2, varscan2
- GOLPH3 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV54062039; called by muse, mutect2, varscan2
- GPRIN1 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.199); catalogued as COSV56135092; called by muse, mutect2, varscan2
- GPS1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.631); catalogued as COSV57650761; called by muse, mutect2, varscan2
- HELZ | c.5384C>G p.S1795C | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.219); catalogued as COSV62379949; called by muse, mutect2
- HOXD13 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV101184108; called by muse, varscan2
- IRF8 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs34712374; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs145043086; called by muse, mutect2, varscan2
- KCNK2 | c.306C>G p.F102L (on ENST00000444842 / NM_001017425.3; = p.F87L on NM_014217.4) | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV67204666, COSV67208444; called by muse, mutect2
- KDM5C | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100855391, COSV62890812; called by muse, mutect2, varscan2
- KIAA0753 | c.2549C>T p.P850L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); catalogued as COSV63818297; called by muse, mutect2, varscan2
- LCMT2 | c.2010C>G p.F670L | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV59791326; called by muse, mutect2, varscan2
- LMX1B | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62741053; called by muse, mutect2
- MAN2C1 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51235881; called by muse, mutect2, varscan2
- MAP3K4 | c.847T>G p.F283V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV62336588; called by muse, mutect2
- MOB1B | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | catalogued as COSV58674690; called by muse, mutect2, varscan2
- MTOR | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV63869623; called by muse, mutect2, varscan2
- MTR | c.2840A>C p.E947A | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV63965942; called by muse, mutect2, varscan2
- MUC17 | c.8879C>A p.T2960N | Missense Mutation (SNP) | VAF 123/354 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs766216835, COSV60297705; called by muse, mutect2, varscan2
- MYH1 | c.5026G>T p.A1676S | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV56853865; called by muse, mutect2, varscan2
- MYO6 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.077); catalogued as COSV64120459; called by muse, mutect2
- MYOCD | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552203360, COSV58496778; called by muse, mutect2, varscan2
- NKD2 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56893851; called by muse, mutect2, varscan2
- NOTCH1 | c.4274G>T p.C1425F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53075762; called by muse, mutect2, varscan2
- NUP205 | c.4671+1G>T p.X1557_splice | Splice Site (SNP) | VAF 42/113 reads (37%) | catalogued as COSV53663682; called by muse, mutect2, varscan2
- OIP5 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.221); catalogued as COSV99530710; called by muse, mutect2, varscan2
- OR52B2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs764911816, COSV73209518; called by muse, mutect2, varscan2
- OR5AS1 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 160/481 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV57982683; called by muse, mutect2, varscan2
- OR6Y1 | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 130/252 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56930641; called by muse, mutect2, varscan2
- OXSM | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV55002283; called by muse, mutect2
- PCDHB10 | c.2297T>C p.F766S | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV53381883; called by muse, mutect2, varscan2
- PCDHB14 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.314); catalogued as COSV53390110; called by muse, mutect2, varscan2
- POLR2C | c.302_303insA p.F101Lfs*9 | Frame Shift Ins (INS) | VAF 35/134 reads (26%) | catalogued as COSV99538187; called by mutect2, pindel, varscan2
- PPP3R2 | c.115A>T p.S39C | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100701353; called by muse, mutect2, varscan2
- PRICKLE2 | c.343G>A p.E115K (on ENST00000295902; = p.E59K on NM_198859.4) | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV55769958; called by muse, mutect2
- PSIP1 | c.305C>G p.S102* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as COSV66254211; called by muse, mutect2, varscan2
- RAB11FIP2 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV62925844; called by muse, mutect2, varscan2
- RAB11FIP4 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV57931443; called by muse, mutect2, varscan2
- RAB3GAP2 | c.372A>T p.L124F | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV52966666; called by muse, mutect2, varscan2
- RBBP6 | c.3779G>T p.G1260V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV60507414; called by muse, mutect2, varscan2
- RCBTB1 | c.930G>C p.W310C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51635943; called by muse, mutect2, varscan2
- RDH8 | c.826C>T p.Q276* (on ENST00000651512; = p.Q256* on NM_015725.4) | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV50676721; called by muse, mutect2, varscan2
- REV3L | c.4333G>T p.G1445* | Nonsense Mutation (SNP) | VAF 48/176 reads (27%) | catalogued as COSV62621750; called by muse, mutect2, varscan2
- RGL2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.086); catalogued as COSV69915736; called by muse, mutect2
- RIPOR3 | c.2206C>G p.R736G | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as rs372814425, COSV50396569; called by muse, mutect2, varscan2
- SCN9A | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV57618495; called by muse, mutect2, varscan2
- SELENON | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs767530943, COSV62525657; called by muse, mutect2, varscan2
- SETD4 | c.210G>C p.E70D | Missense Mutation (SNP) | VAF 120/319 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.303); catalogued as COSV59773281; called by muse, mutect2, varscan2
- SFXN3 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1013041373, COSV56520984; called by muse, mutect2
- SIPA1L1 | c.3222G>T p.K1074N | Missense Mutation (SNP) | VAF 76/130 reads (58%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as COSV62172304; called by muse, mutect2, varscan2
- SMURF2 | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52318057; called by muse, mutect2, varscan2
- SORL1 | c.2126C>T p.S709L | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52759240; called by muse, mutect2
- SPAG16 | c.961G>C p.D321H | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV59098029, COSV59111493; called by muse, mutect2
- SPICE1 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV55623491; called by muse, mutect2
- TBC1D8 | c.1925T>C p.L642P | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100964264; called by muse, mutect2, varscan2
- THSD4 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as COSV55978703, COSV55983785; called by muse, mutect2
- TLN1 | c.4807G>A p.A1603T | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.317); catalogued as COSV59210194; called by muse, mutect2, varscan2
- TMEM123 | c.379C>G p.Q127E | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as COSV63443890; called by muse, mutect2
- TRIP13 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV51321113; called by muse, mutect2, varscan2
- TTBK1 | c.2926C>T p.R976* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as rs752286077, COSV52494692; called by muse, mutect2, varscan2
- TTN | c.2350G>A p.G784R (on ENST00000591111; = p.G738R on NM_003319.4) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | PolyPhen benign (0.011); catalogued as COSV60230919; called by muse, mutect2, varscan2
- USH2A | c.12929G>T p.S4310I | Missense Mutation (SNP) | VAF 89/174 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as COSV56369866; called by muse, mutect2, varscan2
- USH2A | c.11688C>G p.I3896M | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV56408742; called by muse, mutect2, varscan2
- VTN | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as rs782486508, COSV56872476; called by muse, mutect2
- YEATS2 | c.3097G>A p.G1033R | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs779648575, COSV59370037; called by muse, mutect2, varscan2
- ZFHX4 | c.5270C>A p.P1757Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV51480946; called by muse, mutect2, varscan2
- ZNF514 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV54634967; called by muse, mutect2, varscan2
- ZNF781 | c.548T>G p.I183R | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.073); catalogued as COSV62202366; called by muse, mutect2, varscan2
- ZNF878 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 24/173 reads (14%) | catalogued as COSV72156079; called by muse, mutect2, varscan2
- SH3D19 | c.505del p.R169Dfs*63 | Frame Shift Del (DEL) | VAF 123/398 reads (31%) | called by mutect2, pindel, varscan2
- TRAV8-1 | c.28G>T p.G10W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ACE | c.3681G>T p.T1227= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV52011054; called by muse, mutect2, varscan2
- AGER | c.477G>A p.L159= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV66719643; called by muse, mutect2
- ANKFN1 | c.771C>T p.L257= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV59445361; called by muse, mutect2, varscan2
- BEST3 | c.384G>A p.L128= | Silent (SNP) | VAF 6/63 reads (10%) | called by mutect2, varscan2
- BNC2 | c.906G>A p.E302= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as COSV66153342; called by muse, mutect2
- CASP9 | c.1179G>A p.V393= | Silent (SNP) | VAF 62/191 reads (32%) | catalogued as COSV61602143; called by muse, mutect2, varscan2
- CCT2 | c.1515G>C p.L505= | Silent (SNP) | VAF 5/91 reads (5%) | catalogued as rs1190162013, COSV54741034; called by muse, mutect2
- CENPBD1 | c.222G>C p.L74= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99240194; called by muse, mutect2
- CLU | c.672C>T p.R224= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV57067627; called by muse, mutect2, varscan2
- COL18A1 | c.3156G>T p.L1052= (on ENST00000359759 / NM_130444.3; = p.L817= on NM_030582.4) | Silent (SNP) | VAF 8/149 reads (5%) | catalogued as COSV60591729; called by muse, mutect2
- CREB3L3 | c.1092C>T p.H364= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as COSV50238879; called by muse, mutect2, varscan2
- CRYGB | c.453G>A p.E151= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as COSV53680749; called by muse, mutect2, varscan2
- DNAH11 | c.12426C>T p.I4142= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV60970529; called by muse, mutect2, varscan2
- EML2 | c.900C>T p.L300= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs753643080, COSV55602334; called by muse, mutect2, varscan2
- EXOC6B | c.546G>A p.V182= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV55565750; called by muse, mutect2, varscan2
- FBXL6 | c.504C>T p.G168= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100095457; called by muse, mutect2, varscan2
- FETUB | c.843G>T p.V281= | Silent (SNP) | VAF 78/236 reads (33%) | catalogued as COSV54006638; called by muse, mutect2, varscan2
- FLOT1 | c.324G>A p.Q108= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV52544446; called by muse, mutect2
- FOXN1 | c.225C>G p.P75= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs138510671; ClinVar: likely benign; called by muse, mutect2, varscan2
- HCFC1 | c.1896C>T p.I632= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV60075591; called by muse, mutect2, varscan2
- INSR | c.3075C>A p.L1025= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100251320, COSV57162946; called by muse, mutect2, varscan2
- MRPS16 | c.297G>T p.L99= | Silent (SNP) | VAF 52/155 reads (34%) | catalogued as COSV100160159; called by muse, mutect2, varscan2
- MUC5B | c.15381C>A p.A5127= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV71594347; called by muse, mutect2, varscan2
- MYLK4 | c.480C>T p.H160= | Silent (SNP) | VAF 107/277 reads (39%) | catalogued as rs1015241407, COSV51146975; called by muse, mutect2, varscan2
- NSUN4 | c.1104C>G p.L368= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV61063651; called by muse, mutect2
- OR13C8 | c.678G>A p.L226= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as COSV58611930; called by muse, mutect2
- OR8H2 | c.534C>T p.F178= | Silent (SNP) | VAF 39/292 reads (13%) | catalogued as COSV57944814; called by muse, mutect2, varscan2
- PCDHA8 | c.1365C>T p.F455= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs1554139276, COSV65334617; called by muse, mutect2, varscan2
- PGBD5 | c.570G>C p.L190= (on ENST00000525115; = p.L259= on NM_001258311.2) | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV58411854, COSV58412880; called by muse, mutect2
- POTEE | c.405C>T p.V135= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV58226104; called by muse, mutect2, varscan2
- PPP3R2 | c.114G>A p.L38= | Silent (SNP) | VAF 54/144 reads (38%) | catalogued as COSV100701354; called by muse, varscan2
- PRKCSH | c.1461A>G p.K487= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs369863173; called by muse, mutect2, varscan2
- PSG5 | c.681C>G p.R227= | Silent (SNP) | VAF 65/205 reads (32%) | catalogued as COSV61654851; called by muse, mutect2, varscan2
- SIGLEC9 | c.576C>T p.T192= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as rs1184843186, COSV51586588; called by muse, mutect2, varscan2
- SLC3A2 | c.1791C>T p.L597= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as COSV58604353; called by muse, mutect2, varscan2
- SMAD5 | c.573C>T p.S191= | Silent (SNP) | VAF 77/231 reads (33%) | catalogued as rs1207666180, COSV72597499; called by muse, mutect2, varscan2
- SRFBP1 | c.534G>A p.K178= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV100232613; called by muse, mutect2, varscan2
- SYNJ2 | c.1590C>A p.I530= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as COSV62899518, COSV62900134, COSV62900655; called by muse, mutect2
- TBC1D8 | c.1926C>T p.L642= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100964261; called by muse, mutect2, varscan2
- VPS11 | c.189C>T p.F63= (on ENST00000620429; = p.F607= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 11/245 reads (4%) | catalogued as COSV56186458; called by muse, mutect2
- ZBTB7B | c.576G>T p.P192= (on ENST00000292176; = p.P226= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV52694128; called by muse, mutect2, varscan2
- ZNF195 | c.1422C>T p.V474= (on ENST00000399602 / NM_001130520.3; = p.V402= on NM_007152.5) | Silent (SNP) | VAF 65/157 reads (41%) | catalogued as COSV99137579; called by muse, mutect2, varscan2
- BIRC8 | n.1608G>A | RNA (SNP) | VAF 7/109 reads (6%) | catalogued as COSV58843617; called by muse, mutect2
- CREM | c.891-383C>A | Intron (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100414946, COSV100414953; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.569G>A | RNA (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- SENP1 | c.221-295A>G | Intron (SNP) | VAF 34/78 reads (44%) | catalogued as COSV99136785; called by muse, mutect2, varscan2
